Gene-level copy-number profile of tumor specimen TCGA-90-A4EE-01A from TCGA case TCGA-90-A4EE, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.9 years (19,676 days).
Specimen TCGA-90-A4EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e9fff7e4-acf9-4e07-8237-57cc3764b567.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-90-A4EE-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b086b5a-52b0-46c3-9148-88581abbebb5

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 28,119; copy number 2: 23,458; copy number 3: 6,312; copy number 4: 1,685; copy number 5: 68; copy number 6: 10; copy number 8: 13; copy number 9: 26; copy number 11: 15; copy number 12: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-90-A4EE-01A-11D-A256-01): tumor purity 0.42, ploidy 1.67, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:24,542,952–26,118,408, 9 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr15:95,638,316–99,916,818, 87 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 8,137 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr2:42,440,377–68,261,230, 424 genes, copy number 3 (broad region; genes not listed).
- chr2:94,912,432–106,305,197, 269 genes, copy number 3–4 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 3–4 (broad region; genes not listed).
- chr5:659,862–27,496,994, 402 genes, copy number 3–8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:100,916,523–107,963,516, 119 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr8:108,606,850–128,564,679, 236 genes, copy number 3–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:65,879,837–70,436,584, 207 genes, copy number 3–12 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 11: AP001271.1.
- chr12:66,767–34,249,958, 850 genes, copy number 4 (broad region; genes not listed).
- chr14:26,443,090–27,295,516, 9 genes, copy number 4 (within-gene range 1–4): NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr15:83,962,176–85,958,971, 75 genes, copy number 3 (broad region; genes not listed).
- chr15:93,589,867–94,550,572, 14 genes, copy number 5 (within-gene range 2–5): AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2.
- chr17:43,473,585–79,742,219, 1,112 genes, copy number 3 (broad region; genes not listed).
- chr18:30,290,161–31,426,988, 14 genes, copy number 3 (within-gene range 2–3): AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P.
- chr18:31,382,317–31,382,430, 1 gene, copy number 3: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 26,254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
